Somatic mutation profile of tumor specimen MP2PRT-PATKUJ-TBP1-A (aliquot MP2PRT-PATKUJ-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATKUJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,827 days).
Specimen MP2PRT-PATKUJ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc84c72a-2014-46c4-b509-2b1ea4888a2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATKUJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATKUJ-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd5e18a3-8041-4b78-8345-7840522ff7a6

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRA1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 29/527 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs375377575; called by muse, mutect2
- H2AC11 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60362252; called by muse, mutect2
- STOML3 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs533210440, COSV65510570; called by muse, mutect2
- JAG1 | c.2480C>T p.S827L | Missense Mutation (SNP) | VAF 13/485 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- KCNH7 | c.1431G>C p.Q477H | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.722); called by muse, mutect2
- POU1F1 | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- SPEM1 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 36/800 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.667); called by muse, mutect2
- ALDH1B1 | c.147C>T p.V49= | Silent (SNP) | VAF 28/720 reads (4%) | catalogued as rs1409011618; called by muse, mutect2
- WDR90 | c.4312-22G>T | Intron (SNP) | VAF 36/825 reads (4%) | called by muse, mutect2
